Gene-level copy-number profile of tumor specimen TCGA-OR-A5KW-01A from TCGA case TCGA-OR-A5KW, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 55.7 years (20,328 days).
Specimen TCGA-OR-A5KW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.c49aaf3f-7f87-42fc-b5a9-ddb5661464e3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5KW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/263b60fe-963f-43bb-9998-0e9da1a71da7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 7; copy number 2: 35,686; copy number 3: 58; copy number 4: 22,721; copy number 5: 18; copy number 6: 1,008; copy number 8: 204; copy number 10: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5KW-01A-11D-A29H-01): tumor purity 0.95, ploidy 1.4, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,738,615–248,146,086, 28 genes: OR14K1, OR1C1, OR9H1P, OR14A16, HSD17B7P1, OR6R1P, OR11L1, TRIM58, OR2W3, OR2T8, OR2AJ1, CLK3P2, OR2X1P, OR2L8, OR2AK2, OR2L9P, OR2L1P, Y_RNA, OR2L6P, OR2L5, Y_RNA, OR2L2, Y_RNA, OR2L3, OR2T32P, OR2L13, OR2M1P, OR2M5.
- chr3:117,026,698–117,027,039, 1 gene: PTMAP8.
- chr4:182,143,987–182,803,024, 5 genes (within-gene range 0–2): TENM3, AC108142.1, MIR1305, RNU2-34P, RN7SKP67.
- chr10:27,397,121–27,414,368, 1 gene: PTCHD3.
- chr22:29,058,672–29,061,844, 1 gene: C22orf31.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,303 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,273,587–38,300,322, 5 genes, copy number 8: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr14:20,556,093–25,432,234, 349 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr14:35,121,846–35,826,765, 22 genes, copy number 6 (within-gene range 2–6): PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2.
- chr14:64,084,232–64,338,112, 1 gene, copy number 6 (within-gene range 2–6): ESR2.
- chr14:64,329,431–64,601,644, 16 genes, copy number 6: AL161756.1, TEX21P, AL161756.3, AL161756.2, MTHFD1, AL122035.1, AL122035.2, ZBTB25, AKAP5, ZBTB1, AL049869.2, AL049869.3, HSPA2, PPP1R36, AL049869.1, NUP50P1.
- chr14:87,710,419–88,180,198, 12 genes, copy number 6 (within-gene range 5–6): AL359237.1, AL136501.1, GALC, SHLD2P2, RNU6-835P, GPR65, AL157955.1, LINC01147, LINC01146, AL133279.2, AL133279.3, AL133279.1.
- chr14:89,124,871–89,619,149, 1 gene, copy number 6 (within-gene range 2–6): FOXN3.
- chr14:89,290,205–89,409,469, 4 genes, copy number 6: CAP2P1, AL357093.2, AL357093.1, AL356805.1.
- chr14:89,417,354–89,650,903, 5 genes, copy number 6–8: FOXN3-AS1, FOXN3-AS2, RN7SKP107, AL137230.1, Y_RNA.
- chr14:95,686,426–97,217,778, 36 genes, copy number 6 (within-gene range 2–6): TCL1B, TCL1A, AL139020.1, AL133167.1, TUNAR, AL137190.1, C14orf132, BDKRB2, AL355102.2, AL355102.1, CKS1BP1, AL355102.5, BDKRB1, AL355102.4, AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA, AL137786.1, RN7SKP108, AL137786.2, LINC02299, AL137786.3, VRK1, LINC00618, AL049833.3, AL049833.4, AL049833.2, AL049833.1, LINC02304, AL158800.1.
- chr14:99,971,449–100,144,236, 1 gene, copy number 6 (within-gene range 2–6): EVL.
- chr14:100,052,803–101,278,318, 148 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr14:102,341,102–106,146,131, 208 genes, copy number 6 (broad region; genes not listed).
- chr19:48,170,680–54,339,162, 495 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
